Somatic mutation profile of tumor specimen TCGA-13-1507-01A (aliquot TCGA-13-1507-01A-01W-0549-09) from TCGA case TCGA-13-1507, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 77.9 years (28,445 days).
Specimen TCGA-13-1507-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de7c91f2-be21-4a84-947d-7d7201ec7ff7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-1507-10A (Blood Derived Normal), aliquot TCGA-13-1507-10A-01W-0550-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a18afa30-4a2c-431f-b68c-38fa63b3cfcd

The open-access MAF lists 97 somatic variants for this specimen: 79 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 17, Frame Shift Del 3, Nonsense Mutation 3, Splice Site 2, Frame Shift Ins 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.842C>T p.S281L | Missense Mutation (SNP) | VAF 536/2327 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV64671597; called by muse, mutect2, varscan2
- ALAS2 | c.892G>C p.A298P | Missense Mutation (SNP) | VAF 32/334 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100238005; called by muse, mutect2
- ANKRD44 | c.2206G>A p.G736R | Missense Mutation (SNP) | VAF 91/384 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV56550552; called by muse, mutect2, varscan2
- APEX1 | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs367614890; called by muse, mutect2, varscan2
- ATF1 | c.211T>A p.L71I | Missense Mutation (SNP) | VAF 55/163 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV50394106; called by muse, mutect2, varscan2
- ATRX | c.6303A>C p.E2101D | Missense Mutation (SNP) | VAF 75/220 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.191); catalogued as COSV100970166; called by muse, mutect2, varscan2
- CCAR1 | c.600G>C p.W200C | Missense Mutation (SNP) | VAF 57/178 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56267929; called by muse, mutect2, varscan2
- CDCA4 | c.199C>T p.R67W | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1410674637, COSV100288282, COSV60315089; called by muse, mutect2, varscan2
- CHST10 | c.276C>A p.C92* | Nonsense Mutation (SNP) | VAF 88/433 reads (20%) | catalogued as COSV51804436; called by muse, mutect2, varscan2
- DDX39A | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1274503347, COSV54390656; called by muse, mutect2, varscan2
- DENND4B | c.4241A>T p.E1414V | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as COSV63407535; called by muse, mutect2
- DPYD | c.1524+2T>A p.X508_splice | Splice Site (SNP) | VAF 69/259 reads (27%) | catalogued as COSV64592420; called by muse, mutect2, varscan2
- EIF4G1 | c.1058C>G p.S353C (on ENST00000346169 / NM_198241.3; = p.S157C on NM_004953.5) | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as COSV100071528; called by muse, mutect2
- EXOC4 | c.1928A>G p.D643G | Missense Mutation (SNP) | VAF 265/1126 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV54086509; called by muse, mutect2, varscan2
- FGB | c.1255G>T p.D419Y | Missense Mutation (SNP) | VAF 33/176 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57417659; called by muse, mutect2, varscan2
- FLG2 | c.5576A>C p.Q1859P | Missense Mutation (SNP) | VAF 60/595 reads (10%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.695); catalogued as COSV66167086; called by muse, mutect2
- FPGT | c.1780del p.E594Nfs*5 | Frame Shift Del (DEL) | VAF 27/76 reads (36%) | catalogued as COSV63846599; called by mutect2, pindel, varscan2
- GLYATL2 | c.378T>A p.D126E | Missense Mutation (SNP) | VAF 73/280 reads (26%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.868); catalogued as COSV54849246; called by muse, mutect2, varscan2
- GPRC5C | c.196G>A p.A66T (on ENST00000652232; = p.A21T on NM_018653.4) | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as COSV100702917, COSV61235645; called by muse, mutect2, varscan2
- HHAT | c.1043G>A p.R348K | Missense Mutation (SNP) | VAF 44/188 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.957); catalogued as COSV54792598; called by muse, mutect2
- KDM3B | c.2623C>A p.L875M | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.896); catalogued as COSV58688557, COSV58688946; called by muse, mutect2, varscan2
- LDLR | c.2543C>T p.P848L | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52941991; called by muse, mutect2, varscan2
- LMCD1 | c.976C>G p.L326V | Missense Mutation (SNP) | VAF 120/558 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.433); catalogued as COSV50087467; called by muse, mutect2, varscan2
- LPCAT1 | c.1520C>T p.A507V | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as rs1469632956, COSV52035933; called by muse, mutect2, varscan2
- LRRC4C | c.259C>G p.Q87E | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.018); catalogued as COSV53419607; called by muse, mutect2, varscan2
- MATN2 | c.2227G>T p.E743* | Nonsense Mutation (SNP) | VAF 27/116 reads (23%) | catalogued as COSV54707758; called by muse, mutect2, varscan2
- MLH1 | c.559A>T p.N187Y | Missense Mutation (SNP) | VAF 165/720 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV51615123; called by muse, mutect2, varscan2
- MYH1 | c.2261A>T p.D754V | Missense Mutation (SNP) | VAF 80/258 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.222); catalogued as COSV56844727; called by muse, mutect2, varscan2
- MYH4 | c.1447T>G p.F483V | Missense Mutation (SNP) | VAF 47/323 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as COSV55113674; called by muse, mutect2, varscan2
- NIPBL | c.5752A>G p.T1918A | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs199639172, COSV56944604; called by muse, mutect2, varscan2
- OBSCN | c.4554C>G p.S1518R | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.233); catalogued as COSV52748551; called by muse, mutect2
- OR2C3 | c.635T>G p.L212R | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV63574574; called by muse, mutect2, varscan2
- PARP11 | c.745A>G p.K249E | Missense Mutation (SNP) | VAF 88/382 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.473); catalogued as rs1182851082, COSV57393837; called by muse, mutect2, varscan2
- PCDH1 | c.2234A>T p.D745V | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54611725; called by muse, mutect2, varscan2
- PGM5 | c.1069G>T p.V357L | Missense Mutation (SNP) | VAF 125/343 reads (36%) | SIFT tolerated (0.74); PolyPhen benign (0.009); catalogued as COSV67163058; called by muse, mutect2, varscan2
- PHEX | c.1147C>G p.Q383E | Missense Mutation (SNP) | VAF 148/703 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as COSV65074161; called by muse, mutect2, varscan2
- PITPNA | c.406G>A p.V136M | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs747074455, COSV57932487; called by muse, mutect2, varscan2
- PKHD1L1 | c.5645G>A p.C1882Y | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758289780, COSV101006921, COSV65738872; called by muse, mutect2, varscan2
- POTEE | c.71T>A p.M24K | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); catalogued as rs1438063732, COSV100387136; called by muse, mutect2, varscan2
- PPM1E | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 150/561 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.405); catalogued as rs754324408, COSV57570552; called by muse, mutect2, varscan2
- PPM1E | c.632A>G p.E211G | Missense Mutation (SNP) | VAF 149/557 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.274); catalogued as COSV100375896; called by muse, mutect2, varscan2
- PPP2R5C | c.1341T>G p.S447R | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV58268816; called by muse, mutect2, varscan2
- PRAMEF15 | c.1108A>G p.N370D | Missense Mutation (SNP) | VAF 108/1134 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs1165501499; called by muse, varscan2
- PREPL | c.1733C>T p.A578V | Missense Mutation (SNP) | VAF 25/219 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150060920, COSV99575952; called by muse, mutect2, varscan2
- PTGDR | c.392G>T p.W131L | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.739); catalogued as COSV60093253; called by muse, mutect2, varscan2
- PTPRT | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 109/539 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.048); catalogued as COSV61965297; called by muse, mutect2, varscan2
- RAD18 | c.1466G>C p.R489T | Missense Mutation (SNP) | VAF 75/353 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV53749415; called by muse, mutect2, varscan2
- RBM33 | c.2552C>G p.S851* | Nonsense Mutation (SNP) | VAF 3/23 reads (13%) | catalogued as COSV56629757; called by muse, mutect2
- RBM7 | c.501A>T p.Q167H | Missense Mutation (SNP) | VAF 69/345 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV64955450; called by muse, mutect2, varscan2
- RIPOR3 | c.2248C>T p.P750S | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.095); catalogued as rs766262029, COSV50386034; called by muse, mutect2, varscan2
- RYR2 | c.5234A>C p.K1745T | Missense Mutation (SNP) | VAF 43/213 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.083); catalogued as COSV63668244; called by muse, mutect2, varscan2
- SCNM1 | c.550C>A p.P184T | Missense Mutation (SNP) | VAF 135/485 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.201); catalogued as rs771056233, COSV54859656; called by muse, mutect2, varscan2
- SDR39U1 | c.149C>G p.P50R | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771562164, COSV52164674; called by muse, mutect2
- SETDB1 | c.1511C>G p.S504C | Missense Mutation (SNP) | VAF 77/285 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV54978292; called by muse, mutect2, varscan2
- SHC4 | c.1489C>A p.P497T | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT tolerated (0.3); PolyPhen benign (0.028); catalogued as COSV60109973; called by muse, mutect2, varscan2
- SLC22A3 | c.1666C>T p.L556F | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.147); catalogued as COSV51710806; called by muse, mutect2, varscan2
- SLC38A5 | c.1212C>T p.I404= | Splice Region (SNP) | VAF 75/215 reads (35%) | catalogued as rs201040223, COSV58333543; called by muse, mutect2, varscan2
- SLC9A9 | c.383C>T p.T128I | Missense Mutation (SNP) | VAF 82/344 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV57220432; called by muse, mutect2, varscan2
- SLCO1B1 | c.1352A>T p.H451L | Missense Mutation (SNP) | VAF 47/201 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV57008053; called by muse, mutect2, varscan2
- STRN4 | c.1183G>A p.G395R | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.168); catalogued as rs751050236, COSV54419203, COSV99624043; called by muse, mutect2
- STXBP1 | c.1778G>A p.S593N | Missense Mutation (SNP) | VAF 72/195 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV58852212; called by muse, mutect2, varscan2
- SYNPO2 | c.3065C>T p.S1022L | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.316); catalogued as rs774034168, COSV61107652; called by muse, mutect2, varscan2
- TAFA2 | c.178G>C p.E60Q | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV69173056, COSV69173447; called by muse, mutect2, varscan2
- TLN2 | c.7375-1G>A p.X2459_splice | Splice Site (SNP) | VAF 68/107 reads (64%) | catalogued as COSV60886555; called by muse, mutect2, varscan2
- TMEM131 | c.1448T>C p.V483A | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.452); catalogued as COSV51771319; called by muse, mutect2, varscan2
- TP53 | c.419_425del p.T140Mfs*28 | Frame Shift Del (DEL) | VAF 96/133 reads (72%) | catalogued as COSV52784142; called by mutect2, pindel, varscan2
- TPP2 | c.983G>C p.S328T | Missense Mutation (SNP) | VAF 56/206 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV65751354; called by muse, mutect2, varscan2
- TUBGCP4 | c.1204A>C p.K402Q | Missense Mutation (SNP) | VAF 96/347 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.411); catalogued as COSV53018047; called by muse, mutect2, varscan2
- WFIKKN2 | c.486G>C p.E162D | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV60958055; called by muse, mutect2, varscan2
- WNT4 | c.319C>T p.R107W | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51602926; called by muse, mutect2, varscan2
- YBX1 | c.446C>G p.P149R | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.2); catalogued as COSV58437480; called by muse, mutect2, varscan2
- ZC3H6 | c.461A>G p.D154G | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.175); catalogued as COSV59666335; called by muse, mutect2, varscan2
- ZMYM6 | c.1580A>G p.N527S | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.497); catalogued as COSV64120330; called by muse, mutect2, varscan2
- ZNF224 | c.1355G>T p.G452V | Missense Mutation (SNP) | VAF 33/188 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV61241738; called by muse, mutect2, varscan2
- ZNF441 | c.1724G>A p.R575Q | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT tolerated (0.74); PolyPhen benign (0.009); catalogued as rs1438217932, COSV63539358; called by muse, mutect2
- ZNF608 | c.2194C>G p.L732V | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.546); catalogued as COSV60435798; called by muse, mutect2, varscan2
- MACF1 | c.18035C>G p.A6012G (on ENST00000372915; = p.A4057G on NM_012090.5) | Missense Mutation (SNP) | VAF 39/204 reads (19%) | called by muse, mutect2, varscan2
- RPN1 | c.786dup p.R263Tfs*3 | Frame Shift Ins (INS) | VAF 104/317 reads (33%) | called by mutect2, pindel, varscan2
- VPS13C | c.612_618del p.Y205Mfs*22 (on ENST00000644861 / NM_020821.3; = p.Y162Mfs*22 on NM_017684.5) | Frame Shift Del (DEL) | VAF 23/100 reads (23%) | called by mutect2, pindel, varscan2
- BACH2 | c.2490T>C p.C830= | Silent (SNP) | VAF 292/583 reads (50%) | catalogued as rs756574688, COSV57586182; called by muse, mutect2, varscan2
- C9orf135 | c.120G>A p.K40= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as COSV65874702; called by muse, mutect2, varscan2
- DNAH2 | c.1920C>G p.L640= | Silent (SNP) | VAF 191/757 reads (25%) | catalogued as COSV66717315; called by muse, mutect2, varscan2
- HCAR1 | c.363C>T p.H121= | Silent (SNP) | VAF 90/111 reads (81%) | catalogued as COSV63672035; called by muse, mutect2, varscan2
- ISX | c.561G>A p.S187= | Silent (SNP) | VAF 106/351 reads (30%) | catalogued as rs202084562, COSV58085769; called by muse, mutect2, varscan2
- KLK12 | c.483C>T p.C161= | Silent (SNP) | VAF 28/146 reads (19%) | catalogued as COSV51576023, COSV51578354; called by muse, mutect2, varscan2
- MC2R | c.879C>T p.C293= | Silent (SNP) | VAF 22/99 reads (22%) | catalogued as COSV59617250; called by muse, mutect2, varscan2
- MICB | c.9G>T p.L3= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV99357335; called by muse, varscan2
- NADK2 | c.306A>C p.A102= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as COSV99237200; called by muse, mutect2
- OR1Q1 | c.699C>T p.G233= | Silent (SNP) | VAF 12/136 reads (9%) | catalogued as COSV52917416, COSV99939178; called by muse, mutect2
- PLEKHB1 | c.153G>T p.L51= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV57049093; called by muse, mutect2, varscan2
- RELB | c.1116C>G p.V372= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as rs758834064, COSV55508624; called by muse, mutect2, varscan2
- SLC33A1 | c.894C>T p.Y298= | Silent (SNP) | VAF 15/120 reads (13%) | catalogued as COSV63946777; called by muse, mutect2, varscan2
- SV2A | c.1197G>T p.T399= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as rs375397567, COSV64964660; called by muse, mutect2, varscan2
- TCF20 | c.3180C>G p.A1060= | Silent (SNP) | VAF 47/129 reads (36%) | catalogued as COSV59488943, COSV59491659; called by muse, mutect2, varscan2
- USH2A | c.9774G>T p.R3258= | Silent (SNP) | VAF 32/125 reads (26%) | catalogued as COSV56336315; called by muse, mutect2, varscan2
- ZNF592 | c.3093C>T p.H1031= | Silent (SNP) | VAF 58/181 reads (32%) | catalogued as COSV55435411; called by muse, mutect2, varscan2
- KCNAB1 | c.276-129496G>A | Intron (SNP) | VAF 27/134 reads (20%) | catalogued as COSV56742270; called by muse, mutect2, varscan2
